National Lung Screening Trial (NLST) participant 100697 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 57 years; Gender: male; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 22): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 160 mA, 40 effective mAs, display field of view 34 cm, reconstruction filter Siemens, other.
- T1 (day 323): Negative screen, significant abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 140 kVp, 160 mA, 40 effective mAs, display field of view 35 cm, reconstruction filter Siemens B30 / Siemens B50F.
- T2 (day 737): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 75 mA, 43 effective mAs, display field of view 35 cm, reconstruction filter GE Standard / GE Bone.

Abnormalities recorded by the reading radiologist on the CT screens (11 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 13 mm, longest perpendicular diameter 13 mm; margins poorly defined; predominant attenuation soft tissue; greatest diameter on CT slice 105.
- T0 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; margins could not be determined; predominant attenuation could not be determined; greatest diameter on CT slice 90.
- T0 abnormality 3: Other potentially significant abnormality above the diaphragm.
- T1 abnormality 1: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T1 abnormality 2: Emphysema.
- T1 abnormality 3: Other minor abnormality noted.
- T1 abnormality 4: Other potentially significant abnormality above the diaphragm; pre-existing on earlier images (earliest visible day 22); interval change warrants further investigation.
- T1 abnormality 5: Atelectasis, segmental or greater.
- T1 abnormality 6: Other minor abnormality noted.
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 19 mm, longest perpendicular diameter 18 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 73; pre-existing on earlier images (earliest visible day 22); interval growth; no suspicious change in attenuation.
- T2 abnormality 2: Atelectasis, segmental or greater.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a positive screen; study year of the first confirmed lung cancer: T2; the diagnosis is linked to a positive screen through the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 806, study year T2. Site: middle lobe of lung (ICD-O-3 C34.2), determined from histology. Primary tumour location: right middle lobe. Histology: carcinoid tumor, NOS (ICD-O-3 8240/3). Grade: unspecified in pathology report. Tumour size on pathology: 15 mm. AJCC 6th edition staging: carcinoid, stage not assessed, the best stage; clinical T1 N0 M0; pathologic T1 N0 M0. AJCC 7th edition staging: stage IA; clinical T1a N0 M0; pathologic T1a N0 M0. Summary stage: localized.

Follow-up
Last known free of lung cancer: day 673.
